Gene-level copy-number profile of specimen HCM-BROD-0924-C34-85A from HCMI case HCM-BROD-0924-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 55.3 years (20,207 days).
Specimen HCM-BROD-0924-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file eb3c216d-2329-4ee4-93d7-7923e689a80d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0924-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/5640ceb8-338f-4cd5-877e-b74cb6f1561a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 8,702; copy number 2: 29,687; copy number 3: 15,668; copy number 4: 2,552; copy number 5: 2,042; copy number 6: 226; copy number 7: 5; copy number 14: 7.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:64,637,845–64,709,311, 2 genes: AL445665.1, BMS1P11.
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–1): NUTM2B.
- chr16:32,388,135–32,441,159, 2 genes: AC138915.2, PABPC1P13.
- chr21:9,082,601–9,083,101, 1 gene (within-gene range 0–1): SOWAHCP2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,280 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:133,015,004–198,123,232, 1,108 genes, copy number 5–7 (broad region; genes not listed).
- chr4:46,918,900–47,426,447, 2 genes, copy number 5: GABRA4, GABRB1.
- chr8:85,744,543–85,828,467, 7 genes, copy number 14: REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P.
- chr8:93,134,095–145,066,685, 824 genes, copy number 5 (broad region; genes not listed).
- chr10:274,190–689,668, 1 gene, copy number 5 (within-gene range 1–5): DIP2C.
- chr10:430,239–7,118,469, 123 genes, copy number 5–6 (broad region; genes not listed).
- chr10:7,158,624–10,174,577, 31 genes, copy number 5: SFMBT2, COX6CP17, AL139125.1, LINC02642, RNU6-535P, AL445070.1, ITIH5, ITIH2, KIN, ATP5F1C, TAF3, AL353754.1, GATA3, GATA3-AS1, AL390294.1, PRPF38AP1, LINC00708, AL390835.1, AC025946.1, AC025946.2, KRT8P37, CHCHD3P1, RNA5SP299, AL355333.1, LINC02676, AC044784.1, LINC00709, HSP90AB7P, LINC02663, LINC02670, ELOCP3.
- chr10:10,365,180–22,003,769, 184 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,994. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
